Somatic mutation profile of tumor specimen MBCProject_0471_T1B_WES (aliquot MBCProject_0471_T1B_WES_1) from CMI case MBCProject_0471, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 53.7 years (19,611 days).
Specimen MBCProject_0471_T1B_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 67a309b3-24a9-4dbc-a5ab-fa5a2bb5b8fd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0471_SALIVA (Saliva), aliquot MBCProject_0471_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c4eca36d-07d2-4475-a11a-0424325f6e63

The open-access MAF lists 36 somatic variants for this specimen: 27 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 7, Frame Shift Del 2, Intron 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 40/289 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABTB2 | c.1535C>T p.P512L | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as rs966509865; called by muse, mutect2, varscan2
- ACSL1 | c.560C>G p.T187R | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (0.79); PolyPhen benign (0.009); catalogued as rs199729148; called by muse, mutect2
- CBFB | c.334G>A p.G112S | Missense Mutation (SNP) | VAF 26/307 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51997398; called by muse, mutect2
- COX18 | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201446949; called by muse, mutect2
- CYFIP2 | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 38/221 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1476300276, COSV59029474; called by muse, mutect2, varscan2
- KIAA0930 | c.1028A>G p.N343S (on ENST00000336156 / NM_001009880.2; = p.N348S on NM_015264.2) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs774355341; called by mutect2, varscan2
- NOX5 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs746885049; called by mutect2, varscan2
- PREX2 | c.1526C>T p.S509F | Missense Mutation (SNP) | VAF 12/370 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55761688; called by muse, mutect2
- PRKCH | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 15/289 reads (5%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.999); catalogued as rs1357586397, COSV60653632; called by muse, mutect2
- PYHIN1 | c.1022C>T p.T341M | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as rs373907087; called by muse, varscan2
- VWA8 | c.2804C>T p.S935L | Missense Mutation (SNP) | VAF 26/226 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs776493606; called by muse, mutect2, varscan2
- DNAH2 | c.10403T>C p.M3468T | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- FOXA1 | c.612C>A p.F204L | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLHL34 | c.1006G>C p.V336L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.59); called by muse, mutect2, varscan2
- KLHL35 | c.1714C>G p.H572D | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAP3K1 | c.639_648del p.K214Qfs*9 | Frame Shift Del (DEL) | VAF 45/265 reads (17%) | called by mutect2, pindel, varscan2
- MAP3K1 | c.2281_2287delinsTAT p.I761Yfs*37 | Frame Shift Del (DEL) | VAF 59/395 reads (15%) | called by pindel, varscan2*
- MKI67 | c.6722G>A p.R2241K | Missense Mutation (SNP) | VAF 9/178 reads (5%) | SIFT tolerated (0.85); PolyPhen possibly damaging (0.579); called by muse, mutect2
- PAX6 | c.789_790insT p.K264* | Frame Shift Ins (INS) | VAF 36/272 reads (13%) | called by mutect2, pindel, varscan2
- PDK3 | c.183G>C p.M61I | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.353); called by muse, mutect2
- SEPTIN14 | c.462T>A p.H154Q | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- SETD2 | c.4054C>G p.Q1352E | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- SGTA | c.653G>T p.S218I | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.066); called by muse, mutect2
- SLC22A16 | c.406T>G p.W136G | Missense Mutation (SNP) | VAF 95/426 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- TENM3 | c.4244T>G p.V1415G | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- VPS18 | c.1385A>T p.E462V | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ATXN10 | c.999G>C p.V333= | Silent (SNP) | VAF 63/466 reads (14%) | called by muse, mutect2, varscan2
- CD300A | c.75G>A p.A25= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as rs771248555, COSV60411342; called by muse, varscan2
- CSMD3 | c.4551A>T p.A1517= (on ENST00000297405 / NM_001363185.1; = p.A1413= on NM_052900.3) | Silent (SNP) | VAF 10/200 reads (5%) | called by muse, mutect2
- GYS1 | c.1080G>A p.Q360= | Silent (SNP) | VAF 22/119 reads (18%) | called by mutect2, varscan2
- MCM2 | c.1836G>A p.S612= | Silent (SNP) | VAF 16/156 reads (10%) | catalogued as rs753889372, COSV54037373; called by muse, mutect2
- MIB1 | c.1632A>G p.Q544= | Silent (SNP) | VAF 63/310 reads (20%) | called by muse, mutect2, varscan2
- XIRP1 | c.420C>T p.D140= | Silent (SNP) | VAF 22/110 reads (20%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505248 del AGG | 5'Flank (DEL) | VAF 15/117 reads (13%) | called by mutect2, pindel, varscan2
- SLC25A36 | c.385+3769G>A | Intron (SNP) | VAF 38/642 reads (6%) | catalogued as rs1219517840; called by muse, mutect2
